Somatic mutation profile of tumor specimen MP2PRT-PASNHD-TMP1-A (aliquot MP2PRT-PASNHD-TMP1-A-1-0-D-A80I-36) from MP2PRT case MP2PRT-PASNHD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.7 years (3,915 days).
Specimen MP2PRT-PASNHD-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c1ee23c1-ca15-4717-b61a-f465130f4ea4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASNHD-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASNHD-NB1-A-1-0-D-A80I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d14d41d1-73ca-4838-9146-b3260e8cb2c2

The open-access MAF lists 22 somatic variants for this specimen: 18 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 14, Silent 4, Frame Shift Del 2, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANO2 | c.1430G>A p.R477H (on ENST00000356134 / NM_001278597.3; = p.R481H on NM_001278596.3) | Missense Mutation (SNP) | VAF 242/537 reads (45%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs760178168, COSV59032910; called by muse, mutect2, varscan2
- CTBS | c.266C>T p.S89L | Missense Mutation (SNP) | VAF 93/264 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs756480476; called by muse, mutect2, varscan2
- DLC1 | c.703C>T p.R235* | Nonsense Mutation (SNP) | VAF 54/347 reads (16%) | catalogued as rs752447193; called by muse, mutect2, varscan2
- MAP3K9 | c.2183C>T p.T728M (on ENST00000554752 / NM_001284230.1; = p.T742M on NM_033141.4) | Missense Mutation (SNP) | VAF 114/744 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.655); catalogued as rs143232244; called by muse, mutect2, varscan2
- NRXN3 | c.362C>T p.T121M | Missense Mutation (SNP) | VAF 115/703 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1436613332; called by muse, mutect2, varscan2
- PSAPL1 | c.196G>A p.V66I | Missense Mutation (SNP) | VAF 309/711 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs762924459; called by muse, mutect2, varscan2
- RHPN1 | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 50/600 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as rs534518055; called by muse, mutect2
- SLC4A2 | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 440/963 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as rs760204657; called by muse, mutect2, varscan2
- SLC9C2 | c.2212C>T p.R738C | Missense Mutation (SNP) | VAF 98/272 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as rs201611790, COSV62944546; called by muse, mutect2, varscan2
- TRIM44 | c.141del p.H48Tfs*44 | Frame Shift Del (DEL) | VAF 272/640 reads (43%) | catalogued as COSV54984609; called by mutect2, pindel*, varscan2
- DOCK5 | c.2318T>C p.L773P | Missense Mutation (SNP) | VAF 123/275 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ERN1 | c.1073A>T p.Y358F | Missense Mutation (SNP) | VAF 180/375 reads (48%) | SIFT tolerated (0.63); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- IGLV4-69 | chr22:22031468 ATTCACACA>TCGGAGGGG | Missense Mutation (ONP) | VAF 97/117 reads (83%) | called by pindel, varscan2*
- MYO3A | c.112G>A p.V38I | Missense Mutation (SNP) | VAF 69/157 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- NLRP6 | c.1865T>G p.L622R | Missense Mutation (SNP) | VAF 314/666 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- PEX10 | c.686T>C p.V229A | Missense Mutation (SNP) | VAF 149/912 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TCF7 | c.472_499delinsG p.P158_N167delinsD | In Frame Del (DEL) | VAF 168/583 reads (29%) | called by pindel, varscan2*
- ZNF865 | c.401del p.P134Lfs*29 | Frame Shift Del (DEL) | VAF 424/1143 reads (37%) | called by mutect2, pindel, varscan2
- IL1RAPL1 | c.348C>T p.Y116= | Silent (SNP) | VAF 186/219 reads (85%) | catalogued as rs771224987, COSV56243740; called by muse, mutect2, varscan2
- KRT72 | c.834G>A p.T278= | Silent (SNP) | VAF 212/470 reads (45%) | catalogued as rs201887205; called by muse, mutect2, varscan2
- MYOM3 | c.2133C>T p.C711= | Silent (SNP) | VAF 229/595 reads (38%) | catalogued as rs759116192; called by muse, mutect2, varscan2
- PCDHA3 | c.1452G>A p.A484= | Silent (SNP) | VAF 136/1106 reads (12%) | called by muse, mutect2, varscan2
